Somatic mutation profile of tumor specimen TCGA-24-1550-01A (aliquot TCGA-24-1550-01A-01W-0551-08) from TCGA case TCGA-24-1550, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.4 years (18,049 days).
Specimen TCGA-24-1550-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad37b641-1734-4386-a74c-4e8fbb67710e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1550-10A (Blood Derived Normal), aliquot TCGA-24-1550-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eb8c521-9d02-4431-a182-9f8847c12f5e

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 8, Nonsense Mutation 4, RNA 2, 5'Flank 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as rs1567556930, COSV52694020, COSV53536519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7400G>A p.R2467K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.384); catalogued as COSV101446772; called by muse, mutect2
- ACVR1B | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV57779763; called by muse, mutect2, varscan2
- ADCY9 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53573942, COSV99569376; called by mutect2, varscan2
- AKAP6 | c.4359_4362del p.C1453Wfs*29 | Frame Shift Del (DEL) | VAF 122/347 reads (35%) | catalogued as rs1179464671; called by mutect2, pindel, varscan2
- ALDOA | c.1019C>A p.A340D (on ENST00000642816 / NM_001243177.4; = p.A286D on NM_184041.5) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100581917; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2006C>A p.S669* | Nonsense Mutation (SNP) | VAF 81/108 reads (75%) | catalogued as COSV99782072; called by muse, mutect2, varscan2
- ATP13A1 | c.2831A>G p.E944G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99179078; called by mutect2, varscan2
- B3GALT1 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs767590633, COSV100002497, COSV59910040; called by muse, mutect2, varscan2
- BIRC6 | c.5229T>A p.H1743Q | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV101427845; called by muse, mutect2, varscan2
- CA6 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV101077370; called by muse, mutect2, varscan2
- CCZ1 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100382687; called by muse, mutect2, varscan2
- CD163 | c.2734A>T p.K912* | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | catalogued as COSV100775655; called by muse, mutect2, varscan2
- CLSPN | c.2967-2A>G p.X989_splice | Splice Site (SNP) | VAF 138/450 reads (31%) | catalogued as COSV99230291; called by muse, mutect2, varscan2
- CNTN3 | c.2729T>C p.V910A | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV99723298; called by muse, mutect2, varscan2
- CSMD3 | c.2869C>A p.L957I (on ENST00000297405 / NM_001363185.1; = p.L853I on NM_052900.3) | Missense Mutation (SNP) | VAF 141/186 reads (76%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as rs746232731, COSV52157753, COSV99824998, COSV99836689; called by muse, mutect2, varscan2
- CTNNA2 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100781762, COSV63582646; called by muse, mutect2
- CUL3 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.207); catalogued as COSV100023770; called by muse, mutect2, varscan2
- DCAF4L2 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); catalogued as rs1431000804, COSV100150497; called by muse, mutect2, varscan2
- DOCK8 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV101209796; called by muse, mutect2
- EP400 | c.1021A>G p.N341D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs1466631572, COSV100200414; called by muse, varscan2
- ESR2 | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 124/329 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV99962828; called by muse, mutect2, varscan2
- FAM184A | c.1193T>A p.V398D | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100137373; called by muse, mutect2, varscan2
- FRY | c.2488A>T p.N830Y | Missense Mutation (SNP) | VAF 79/128 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100968802; called by muse, mutect2, varscan2
- MPV17L2 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1378717998, COSV99717904; called by muse, mutect2, varscan2
- MUC16 | c.41896A>G p.R13966G | Missense Mutation (SNP) | VAF 84/122 reads (69%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.93); catalogued as COSV101109597; called by muse, mutect2, varscan2
- NPRL2 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99204531; called by muse, mutect2, varscan2
- PANK2 | c.1398G>C p.W466C (on ENST00000316562 / NM_153638.3; = p.W175C on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/214 reads (78%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as rs767222898, COSV100262121; called by muse, mutect2, varscan2
- PPM1G | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs1481891496, COSV99277262; called by muse, mutect2, varscan2
- PPP2R2C | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs374362764; called by muse, mutect2, varscan2
- PRUNE2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 139/237 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1175546430, COSV100942784; called by muse, mutect2, varscan2
- PTGIS | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.558); catalogued as COSV99720658; called by muse, mutect2, varscan2
- PTPRB | c.5290C>T p.P1764S | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99715808; called by muse, mutect2, varscan2
- PTPRH | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV99670674; called by muse, mutect2, varscan2
- RP1L1 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762676280, COSV101222955; called by muse, varscan2
- SEMA5B | c.1717T>A p.C573S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530849; called by muse, mutect2, varscan2
- SLC7A1 | c.1157T>C p.I386T | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV101060130; called by muse, mutect2, varscan2
- ST6GAL1 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 101/458 reads (22%) | PolyPhen probably damaging (0.968); catalogued as COSV99398166; called by muse, mutect2, varscan2
- STX5 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99585749; called by muse, mutect2, varscan2
- SULF1 | c.2093A>T p.H698L | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99482157; called by muse, mutect2, varscan2
- TBX22 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 203/497 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100960612; called by muse, mutect2, varscan2
- TTN | c.47336T>C p.V15779A (on ENST00000591111; = p.V8355A on NM_003319.4) | Missense Mutation (SNP) | VAF 171/458 reads (37%) | PolyPhen benign (0); catalogued as rs1295267229, COSV100594424; called by muse, mutect2, varscan2
- UBE3A | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV99216748; called by muse, mutect2, varscan2
- YY2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs551538589, COSV100810675; called by muse, mutect2, varscan2
- ZC3H11A | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV100142144; called by muse, mutect2, varscan2
- ZFP64 | c.1839C>A p.D613E | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV99401956; called by muse, mutect2, varscan2
- ZNF543 | c.794A>T p.N265I | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100386636; called by muse, mutect2, varscan2
- MYO6 | c.2937dup p.R980Tfs*5 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- USP34 | c.9470_9478del p.I3157_E3160delinsK | In Frame Del (DEL) | VAF 63/190 reads (33%) | called by mutect2, pindel, varscan2
- ASPH | c.1866A>G p.K622= | Silent (SNP) | VAF 52/377 reads (14%) | catalogued as rs1482024418; called by muse, mutect2, varscan2
- CYP27A1 | c.594G>A p.S198= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as rs1487944910, COSV51469902; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRB1 | c.915G>A p.A305= | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as rs548869600, COSV99780192; called by muse, mutect2, varscan2
- KAT6A | c.1227C>A p.L409= | Silent (SNP) | VAF 101/268 reads (38%) | catalogued as COSV99704387; called by muse, mutect2, varscan2
- PIK3CG | c.2520A>G p.Q840= | Silent (SNP) | VAF 150/438 reads (34%) | catalogued as COSV100782534; called by muse, mutect2, varscan2
- RFPL2 | c.528G>A p.Q176= | Silent (SNP) | VAF 103/160 reads (64%) | catalogued as COSV99964020; called by muse, mutect2, varscan2
- RYR2 | c.8307A>G p.E2769= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1256892565, COSV100767911; called by muse, varscan2
- SPTAN1 | c.3729T>C p.D1243= | Silent (SNP) | VAF 81/116 reads (70%) | catalogued as COSV100823253; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498987 A>T | 5'Flank (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- AR | c.1616+22242T>C | Intron (SNP) | VAF 16/379 reads (4%) | catalogued as COSV101017408; called by muse, mutect2
- FBXL21P | n.1202A>G | RNA (SNP) | VAF 118/198 reads (60%) | catalogued as COSV99778186; called by muse, mutect2, varscan2
- HMGB1P1 | n.76G>A | RNA (SNP) | VAF 113/425 reads (27%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790532 ins A | 5'Flank (INS) | VAF 32/106 reads (30%) | catalogued as rs1270396760; called by mutect2, varscan2
- ZNF835 | c.-25C>A | 5'UTR (SNP) | VAF 14/170 reads (8%) | catalogued as COSV101606259; called by muse, mutect2
